TCGA case TCGA-BC-A10X — Liver Hepatocellular Carcinoma (TCGA-LIHC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Liver and intrahepatic bile ducts; Tissue source site: UNC. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3dc48ea9-a3c6-437f-af5a-88feb300cc5f

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 52 years; Vital status: Dead; Days to death: 770 days (2.1 years).

Diagnoses (1)
1. Hepatocellular carcinoma, NOS: ICD-O-3 morphology code: 8170/3; ICD-10 code: C22.0; Tissue or organ of origin: Liver; Site of resection or biopsy: Liver; Classification of tumor: primary; Age at diagnosis: 52.4 years (19,140 days); Year of diagnosis: 2002; AJCC staging edition: 5th; AJCC pathologic T: T3a; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0.
   Pathology details: Consistent pathology review: Yes; Vascular invasion present: Yes; Vascular invasion type: Micro.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.

Follow-up (1 entry)
- Days to follow up: 770 days (2.1 years); Disease response: Tumor Free.

Molecular and laboratory tests
- Platelets 602 (unit not recorded by GDC) [Blood test normal range lower: 150; Blood test normal range upper: 440].
- Total Bilirubin 0.3 mg/dL [Blood test normal range lower: 0; Blood test normal range upper: 1.2].
- Alpha Fetoprotein 264 ng/mL.
- Prothrombin time (INR, as labelled on the TCGA clinical form) 1.
- Albumin 3.6 (unit not recorded on the TCGA source form) [Blood test normal range lower: 3.5; Blood test normal range upper: 5].
- Creatinine 0.7 mg/dL [Blood test normal range lower: 0.7; Blood test normal range upper: 1.1].

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 65 kg.

Family history
- Relatives with cancer history count: 2.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-BC-A10X-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 520 mg.
  Slide TCGA-BC-A10X-01A-01-MS1: Section location: Bottom; Percent tumor cells: 50; Percent tumor nuclei: 45; Percent normal cells: 45; Percent necrosis: 0; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide TCGA-BC-A10X-01A-01-TS1: Section location: Top; Percent tumor cells: 82; Percent tumor nuclei: 85; Percent normal cells: 0; Percent necrosis: 3; Percent stromal cells: 15; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-BC-A10X-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-BC-A10X-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Initial weight: 430 mg.
  Slide TCGA-BC-A10X-11A-01-TS1: Section location: Top; Percent tumor cells: 0; Percent tumor nuclei: 0; Percent normal cells: 80; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 3; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Histologic diagnosis: Hepatocellular Carcinoma; Definitive surgical procedure: Lobectomy.
- History hepato carcinoma risk factors: No History of Primary Risk Factors.
- Follow-up form: Tumor status: Tumor free; New tumor event diagnosis indicator: No.
- Follow-up form, New tumor event: New tumor event type: No New Tumor Event.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 770 days; disease-specific survival: no event (censored), 770 days; disease-free interval: no event (censored), 770 days; progression-free interval: no event (censored), 770 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-BC-A10X-01A-11D-A12Y-01): tumor purity 0.5, ploidy 2, whole-genome doublings 0.
